Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3TX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3TX-01A (Primary Tumor).

[page 1 of 4]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone:

Final Report

DIAGNOSIS

A) UTERUS, CERVIX, PARAMETRIA, OVARIES, AND FALLOPIAN TUBES, RADICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:

1. Squamous cell carcinoma of the cervix

a. Histologic grade: Poorly differentiated (G3)

b. Maximum tumor size: 4.9 cm (horizontal extent)

c. Maximum depth of invasion: 0.4 cm

Cervical wall thickness: 0.9 cm

d. Parametrial involvement: Negative

e. Associated CIN: Absent

f. Margins: Clear

g. Angiolymphatic invasion: Absent

h. Three left parametrial lymph nodes negative for carcinoma (0/3)

i. One right parametrial lymph node negative for carcinoma (0/1)

2. Bilateral parametria, vaginal cuff, endometrium, myometrium, ovaries and fallopian tubes negative for carcinoma

3. Additional findings:

a. Uterine weight: 83.9 grams

b. Right ovary with benign cystic follicle

c. Atrophic endometrium

4. See staging parameters below

B) RIGHT PELVIC LYMPH NODES, REGIONAL RESECTION:
Ten lymph nodes negative for carcinoma (0/10)

C) RIGHT PERIAORTIC LYMPH NODES, REGIONAL RESECTION:
Two lymph nodes negative for carcinoma (0/2)

D) LEFT PELVIC LYMPH NODES, REGIONAL RESECTION:
Thirteen lymph nodes negative for carcinoma (0/13)

E) LEFT PERIAORTIC LYMPH NODE, BIOPSY:
One lymph node negative for carcinoma (0/1)

CERVIX CANCER STAGING PARAMETERS

MACROSCOPIC

PROCEDURES

Radical hysterectomy, Bilateral salpingo-oophorectomy,

Regional lymph node dissections

SPECIMEN TYPE

Uterus, cervix, and parametrium, Ovaries, Fallopian tubes,

Regional lymph nodes

TUMOR SITE

Circumferential lesion (all quadrants involved)

MACROSCOPIC TUMOR SIZE

ICD-O-3

Carcinoma, Squamous cell,
NOS

8070/3

Site: Cervix, NOS

C53.9

4-6-12 R0

[page 2 of 4]
[REDACTED]

Greatest dimension: 4.9 cm

MICROSCOPIC

HISTOLOGIC TYPE

Squamous cell carcinoma, keratinizing

HISTOLOGIC GRADE

Poorly differentiated (G3)

MICROSCOPIC TUMOR SIZE

CERVICAL STROMAL INVASION

Maximum horizontal extent: 4.9 cm

Maximum depth of invasion: 0.3 cm

Cervical wall thickness: 0.9 cm

PARAMETRIAL INVOLVEMENT

Absent

ASSOCIATED EPITHELIAL LESIONS

Absent

LYMPHATIC/VASCULAR INVASION

Not identified

MARGINS

Uninvolved by invasive carcinoma

Distance of invasive carcinoma to closest margin: 2.4 cm

Location: Vaginal cuff

Uninvolved by intraepithelial neoplasia

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1b2. (Clinically visible lesion more than 4.0 cm in greatest dimension)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 30

Total positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1b2N0M0

FIGO stage: IB2

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Squamous cell cancer of the cervix

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Uterus, cervix, bilateral tubes and ovaries, radical abdominal hysterectomy

Received is a radical hysterectomy specimen measuring 83.9 gm without attached fallopian tubes and ovaries. It measures 10.5 cm from superior to inferior, 5.0 cm from cornu to cornu and 2.0 cm in thickness. There is approximately 2.5 cm of vaginal cuff present. The anterior portion of the uterus is inked blue and the posterior is inked black. The perimetria is removed and submitted sequentially from medial to lateral. The specimen displays pink-tan slightly ragged serosal surfaces. Upon opening the

[REDACTED]

[page 3 of 4]
[REDACTED]

specimen there is a 4.9 x 3.5 x 2.3 cm exophytic fungating cervical mass. The mass obscures the ectocervix completely. The vaginal cuff margin is grossly free of tumor and is submitted en face. The tumor is located 2.4 cm from the closest vaginal cuff margin (anterior side). On cut section the tumor appears to invade 2-3 mm out of an average cervical wall thickness of 9 mm. Additionally the tumor appears to involve a portion of the endocervix.

The endometrium is tan and glistening and has an average thickness of 0.1 cm. The myometrium is homogeneous pink-tan, has an average thickness of 1.1 cm and is slightly trabeculated. There are no masses or lesions identified in the endomyometrium.

The left ovary measures 1.5 x 1.0 x 0.4 cm and has a pink-tan smooth bosselated external appearance. Cut section shows white-tan parenchyma with no masses or lesions identified. There is a ligated fallopian tube measuring 1.5 cm in length x 0.5 cm in diameter with a fimbriated end. On cut section the tube is patent and stellate throughout.

The right ovary measures 1.3 x 0.6 x 0.4 cm. The cut surface shows yellow-tan parenchyma with multiple small cysts. No masses or lesions are identified. There is a 1.5 cm segment of fimbriated fallopian tube. The tube measures 0.4 cm in diameter and displays a stellate patent lumen throughout.

A gross photograph is taken. Tissue is taken for tumor banking. The specimen is submitted in 33 cassettes. Summary of cassettes:

- 1-6. Right parametrium
- 7-13. Left parametrium
14. Vaginal cuff from 12 o'clock to 3 o'clock, en face
15. Vaginal cuff 3 o'clock to 6 o'clock, en face
16. Vaginal cuff 6 o'clock to 9 o'clock, en face
17. Vaginal cuff 9 o'clock to 12 o'clock, en face
- 18-20. Tumor at deepest point of invasion (anterior-12 o'clock, submitted in thirds sequentially from vaginal cuff to lower uterine segment- upper cut edge is inked yellow)
- 21-23. Tumor at deepest point of invasion (anterior 12-o'clock, submitted in thirds sequentially from vaginal cuff to lower uterine segment- upper cut edge is inked yellow)
- 24-25. Tumor at deepest point of invasion (posterior- 6 o'clock, submitted sequentially from vaginal cuff to lower uterine segment bisected- upper cut edge is inked yellow)
- 26-27. Tumor at deepest point of invasion (posterior- 6 o'clock, submitted sequentially from vaginal cuff to lower uterine segment bisected- upper cut edge is inked yellow)
28. Anterior endomyometrium
29. Posterior endomyometrium
30. Left ovary
31. Left tube
32. Right ovary
33. Right tube

This case is accessioned in

[REDACTED]

B) SOURCE: Lymph node resection, pelvic, right

[REDACTED]

[page 4 of 4]
[REDACTED]

Labeled "right pelvic lymph nodes" are multiple yellow-tan, ragged fatty soft tissues aggregating to 5.5 x 4.8 x 2.5 cm. The tissues are searched for lymph nodes. Six discrete lymph nodes which range from 1.7-4.5 cm in greatest dimension are identified. The specimen is entirely submitted in 12 cassettes as follows:

- B1. One lymph node
- 2. One lymph node, sectioned
- 3. One lymph node, sectioned
- 4. One lymph node, sectioned
- 5,6. One lymph node, sectioned
- 7-9. One lymph node, sectioned
- 10-12. Remaining soft tissues

C) SOURCE: Lymph node resection, right periaortic
Labeled "right periaortic lymph nodes" is a single 1.7 cm tan ragged, fatty soft tissue. The tissue is examined for lymph nodes, and no discrete nodal tissue is identified. The soft tissue is entirely submitted in toto in a single cassette.

D) SOURCE: Lymph node resection, pelvic, left
Labeled "left pelvic lymph nodes" are multiple yellow-tan, ragged fatty soft tissues which aggregate to 5 x 3.5 x 2.8 cm. The tissue is searched for lymph nodes, five lymph nodes which range from 0.7-4 cm in greatest dimension are identified. The specimen is entirely submitted in 8 cassettes as follows:

- D1. Two lymph nodes
- 2. One lymph node
- 3. One lymph node, sectioned
- 4-6. One lymph node, sectioned
- 7,8. Remaining soft tissue

E) SOURCE: Lymph node resection, left aortic
Labeled "left aortic lymph node" are multiple yellow-tan, ragged fatty soft tissues aggregating to 2.2 cm in greatest dimension. The tissues are searched for lymph nodes, a single apparent lymph node measuring 1.3 cm in greatest dimension is identified. The specimen is entirely submitted in two cassettes as follows:

- E1. One lymph node
- 2. Remaining soft tissue
- [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis.
Transcribed by [REDACTED]

Interpreted at

COLLECTED:

ACCESSIONED:

SIGNED:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

- Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

- Order Result History

Lab Status

Order Complete [3]

[REDACTED]

Source: NCI Genomic Data Commons file 83a51e54-9da4-470d-a16d-af76e2e5eef9 (TCGA-FU-A3TX.8206742A-1778-4B5F-AD56-32D9501EDA3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).